Surgical pathology report (de-identified scan), TCGA case TCGA-RN-AAAQ, project TCGA-SARC (Sarcoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RN-AAAQ-01A (Primary Tumor).

ICD O-3
Tumor, malignant peripheral nerve
sheath 9540/3
Site: ^{CLL} Head & neck NOS C49.0
^{path} @ Arm, brachial plexus C47.1

Addendum Microscopic Description:

7/10 5/16/14

A panel of immunohistochemical stains are performed. The tumor cells appear negative for expression of AE1/AE3, HMB-45, smooth muscle actin, MiTF, CD31, desmin, cytokeratin 7, and EMA. They demonstrate diffuse strong immunoreactivity. A CD34 immunostain highlights the background tumor vasculature. The tumor cells exhibit diffuse strong vimentin expression. The calculated MIB-1 labeling index is 15.7%.

Addendum Diagnosis:

Nerve sheath tumor, biopsy resection:

Procedure: Wide resection. Tumor site: Brachial plexus, left arm.

Tumor size: 16.5 cm (greatest dimension) Microscopic extent of tumor: Deep. Other: Brachial plexus.
Histological type: Malignant peripheral nerve sheath tumor. Mitotic rate: 6 mitoses per 10 high power fields. Necrosis: Present- Extent: 50%. Histologic grade: Grade 3. Margins: Cannot be assessed.

Source: NCI Genomic Data Commons file 395cd5fd-e9e8-4fad-90cd-913258f2c257 (TCGA-RN-AAAQ.BB158908-A555-42CB-AC5E-90A16797CFAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).